Somatic mutation profile of tumor specimen MMRF_1640_1_BM_CD138pos (aliquot MMRF_1640_1_BM_CD138pos_T1_KBS5U_L04310) from MMRF case MMRF_1640, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 71.7 years (26,173 days).
Specimen MMRF_1640_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0b0abec3-c7eb-4f86-b75e-9a4d4dbd5f2f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1640_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1640_1_PB_Whole_C3_KBS5U_L04321; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2421c5b5-2d77-47cb-b7c0-ec8f5b355777

The open-access MAF lists 135 somatic variants for this specimen: 50 protein-altering or splice-affecting, 26 silent, 59 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, 3'UTR 33, Silent 26, Intron 18, 5'UTR 3, 3'Flank 2, Nonsense Mutation 2, Splice Region 2, 5'Flank 2, Nonstop Mutation 1, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKR1D1 | c.799G>A p.G267R | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as rs768685155; called by muse, mutect2, varscan2
- ARHGEF15 | c.800G>A p.R267H | Missense Mutation (SNP) | VAF 42/139 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1362528188, COSV62726799; called by muse, mutect2, varscan2
- BASP1 | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 17/152 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.494); catalogued as COSV59471768; called by muse, mutect2, varscan2
- CACNA1E | c.1114C>T p.R372C | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs768773946, COSV62437200; called by muse, mutect2
- CDC45 | c.325G>A p.V109I | Missense Mutation (SNP) | VAF 70/176 reads (40%) | SIFT tolerated (0.54); PolyPhen benign (0.023); catalogued as COSV54248222; called by muse, mutect2, varscan2
- EHD2 | c.1336G>C p.V446L | Missense Mutation (SNP) | VAF 29/181 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.089); catalogued as COSV54407468; called by muse, mutect2
- ENPP6 | c.1162G>A p.V388I | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.026); catalogued as rs202227285; called by muse, mutect2, varscan2
- FLT4 | c.1422C>T p.L474= | Splice Region (SNP) | VAF 15/78 reads (19%) | catalogued as COSV56115208; called by muse, mutect2, varscan2
- HS3ST1 | c.188G>A p.R63H | Missense Mutation (SNP) | VAF 55/69 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1233497406, COSV50023187; called by muse, mutect2, varscan2
- IGLV3-19 | c.143G>C p.S48T | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs117237784; called by muse, varscan2
- IGLV3-25 | c.66G>C p.E22D | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.45); PolyPhen benign (0.03); catalogued as rs376421895; called by muse, varscan2
- IGLV3-25 | c.209G>T p.S70I | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.144); catalogued as rs145801212; called by muse, varscan2
- KIAA1614 | c.1574C>T p.P525L | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as rs1331298534; called by muse, mutect2, varscan2
- KIF2B | c.523G>A p.A175T | Missense Mutation (SNP) | VAF 23/180 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.877); catalogued as COSV52127569; called by muse, mutect2, varscan2
- KMT2C | c.7651C>T p.H2551Y | Missense Mutation (SNP) | VAF 87/184 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs776769083; called by muse, mutect2, varscan2
- LGR5 | c.1535G>C p.G512A | Missense Mutation (SNP) | VAF 68/150 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.02); catalogued as rs780442021; called by muse, mutect2, varscan2
- LIFR | c.629C>A p.P210H | Missense Mutation (SNP) | VAF 51/132 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99665421; called by muse, mutect2, varscan2
- LRRC4B | c.1025C>T p.A342V | Missense Mutation (SNP) | VAF 16/165 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.061); catalogued as COSV65349583; called by muse, mutect2, varscan2
- MORN1 | c.346G>A p.G116S | Missense Mutation (SNP) | VAF 29/37 reads (78%) | SIFT deleterious (0.04); PolyPhen benign (0.164); catalogued as rs115624462; called by muse, mutect2, varscan2
- NALCN | c.2080C>T p.R694C | Missense Mutation (SNP) | VAF 42/44 reads (95%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.551); catalogued as rs569850296, COSV51915517; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NBAS | c.5830G>A p.A1944T | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs773223545, COSV55734366; called by muse, mutect2, varscan2
- PDE1C | c.1148C>G p.A383G | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.173); catalogued as COSV58521910, COSV58529983; called by muse, mutect2
- RPS6KA2 | c.389C>T p.T130M | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760698571, COSV55827635; called by muse, mutect2, varscan2
- RTN2 | c.626C>T p.P209L | Missense Mutation (SNP) | VAF 24/187 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.009); catalogued as rs746817409; called by muse, mutect2, varscan2
- SLC17A1 | c.663T>G p.Y221* | Nonsense Mutation (SNP) | VAF 39/143 reads (27%) | catalogued as COSV55078597; called by muse, mutect2, varscan2
- VPS13D | c.9145C>T p.R3049W | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200361851, COSV50652105; called by muse, mutect2, varscan2
- ZNF831 | c.4906A>G p.I1636V | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as rs745333494; called by muse, mutect2, varscan2
- ADSL | c.535C>T p.L179F | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.727); called by muse, mutect2, varscan2
- BMP5 | c.1363T>G p.*455Eext*2 | Nonstop Mutation (SNP) | VAF 21/50 reads (42%) | called by muse, mutect2, varscan2
- DALRD3 | c.218C>T p.A73V | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- FGF18 | c.5A>T p.Y2F | Missense Mutation (SNP) | VAF 57/87 reads (66%) | SIFT tolerated (0.58); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- FOXO1 | c.459C>G p.S153R | Missense Mutation (SNP) | VAF 9/11 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- FYN | c.787G>A p.V263I | Missense Mutation (SNP) | VAF 39/77 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HERC2 | c.568G>C p.E190Q | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- IFT172 | c.3462T>A p.D1154E | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- KCNK12 | c.1166T>G p.L389R | Missense Mutation (SNP) | VAF 32/60 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- LDB2 | c.1087A>T p.K363* | Nonsense Mutation (SNP) | VAF 8/95 reads (8%) | called by muse, mutect2
- MUC3A | c.496C>T p.P166S | Missense Mutation (SNP) | VAF 22/378 reads (6%) | SIFT deleterious, low confidence (0.03); called by muse, mutect2
- NONO | c.279_282del p.F94Rfs*27 | Frame Shift Del (DEL) | VAF 57/92 reads (62%) | called by mutect2, pindel, varscan2
- NOX4 | c.749C>A p.P250H | Missense Mutation (SNP) | VAF 7/140 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.376); called by muse, mutect2
- NPL | c.355T>C p.W119R | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT tolerated (0.54); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OGDHL | c.461C>A p.T154K | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.434); called by muse, mutect2, varscan2
- PHC2 | c.1668G>T p.E556D (on ENST00000257118 / NM_198040.2; = p.E21D on NM_004427.4) | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.978); called by muse, mutect2
- PPARGC1A | c.272T>A p.V91D | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PPP1R3A | c.2248G>A p.A750T | Missense Mutation (SNP) | VAF 140/277 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- PSMC1 | c.386C>T p.S129L | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.529); called by muse, mutect2, varscan2
- SLC9B2 | c.471A>C p.R157S | Missense Mutation (SNP) | VAF 27/183 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- SLITRK3 | c.1543T>A p.L515I | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- UBTF | c.1954-6C>T | Splice Region (SNP) | VAF 22/87 reads (25%) | called by muse, mutect2, varscan2
- ZNF547 | c.227C>T p.A76V | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.006); called by muse, mutect2
- CBARP | c.243G>A p.A81= (on ENST00000382477; = p.A87= on NM_152769.3) | Silent (SNP) | VAF 42/82 reads (51%) | catalogued as rs369590932; called by muse, mutect2, varscan2
- CCDC102B | c.633A>G p.L211= | Silent (SNP) | VAF 95/133 reads (71%) | called by muse, mutect2, varscan2
- COL16A1 | c.1479A>G p.K493= | Silent (SNP) | VAF 9/47 reads (19%) | called by muse, mutect2, varscan2
- CROCC | c.4422C>T p.L1474= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as rs373265072; called by mutect2, varscan2
- CYFIP1 | c.363A>G p.K121= | Silent (SNP) | VAF 36/162 reads (22%) | called by muse, mutect2, varscan2
- DLG5 | c.3441G>A p.P1147= | Silent (SNP) | VAF 12/80 reads (15%) | catalogued as rs759453399; called by muse, mutect2, varscan2
- DNAJC21 | c.393T>G p.V131= | Silent (SNP) | VAF 64/305 reads (21%) | catalogued as rs766164677; called by muse, mutect2, varscan2
- FBXO7 | c.189G>A p.L63= | Silent (SNP) | VAF 69/259 reads (27%) | catalogued as rs1266354112; called by muse, mutect2, varscan2
- G6PC | c.696A>C p.V232= | Silent (SNP) | VAF 34/113 reads (30%) | called by muse, mutect2, varscan2
- IGHV1-69D | c.42T>C p.A14= | Silent (SNP) | VAF 13/13 reads (100%) | called by mutect2, varscan2
- IGHV2-70D | c.78T>A p.S26= | Silent (SNP) | VAF 40/77 reads (52%) | called by muse, varscan2
- IGLV3-19 | c.63T>G p.S21= | Silent (SNP) | VAF 8/20 reads (40%) | called by muse, varscan2
- IGLV3-25 | c.67C>T p.L23= | Silent (SNP) | VAF 24/52 reads (46%) | catalogued as rs369721805; called by muse, varscan2
- ITGA10 | c.2001G>A p.R667= | Silent (SNP) | VAF 14/44 reads (32%) | called by muse, mutect2, varscan2
- LAMTOR1 | c.90C>T p.T30= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as rs1360728849; called by muse, mutect2, varscan2
- LHX2 | c.153G>A p.A51= | Silent (SNP) | VAF 40/55 reads (73%) | catalogued as rs149553241, COSV101010076; called by muse, mutect2, varscan2
- LRRC30 | c.399G>A p.P133= | Silent (SNP) | VAF 26/123 reads (21%) | called by muse, mutect2, varscan2
- LRRN1 | c.864G>A p.R288= | Silent (SNP) | VAF 16/296 reads (5%) | called by muse, mutect2
- NBAS | c.3639G>A p.E1213= | Silent (SNP) | VAF 57/181 reads (31%) | catalogued as rs1419285872, COSV55729222, COSV55729288; called by muse, mutect2, varscan2
- NECTIN1 | c.1077C>T p.G359= | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as rs780660537, COSV50598007; called by muse, mutect2
- OR8H2 | c.252G>A p.A84= | Silent (SNP) | VAF 192/304 reads (63%) | catalogued as COSV57943731; called by muse, mutect2, varscan2
- RARB | c.717C>T p.I239= (on ENST00000383772 / NM_001290216.2; = p.I232= on NM_000965.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 26/86 reads (30%) | catalogued as rs755865469, COSV58067065; called by muse, mutect2, varscan2
- SMG8 | c.1335T>C p.Y445= | Silent (SNP) | VAF 21/96 reads (22%) | catalogued as rs753386373; called by muse, mutect2, varscan2
- TAGLN | c.153C>G p.G51= | Silent (SNP) | VAF 42/59 reads (71%) | called by muse, mutect2, varscan2
- TENM3 | c.7728C>T p.N2576= | Silent (SNP) | VAF 21/60 reads (35%) | catalogued as rs1376137883; called by muse, mutect2, varscan2
- ZNF860 | c.1386C>G p.T462= | Silent (SNP) | VAF 45/427 reads (11%) | called by muse, mutect2
- AC021218.1 | n.992C>T | RNA (SNP) | VAF 7/44 reads (16%) | catalogued as rs779183184; called by muse, mutect2, varscan2
- AC244517.10 | c.36-9338G>A | Intron (SNP) | VAF 4/16 reads (25%) | called by muse, mutect2
- ADAMTSL1 | c.*958G>A | 3'UTR (SNP) | VAF 41/103 reads (40%) | catalogued as rs975715119; called by muse, mutect2, varscan2
- AK9 | c.3633+13_3633+15del | Intron (DEL) | VAF 5/37 reads (14%) | catalogued as rs201441562; called by pindel, varscan2
- ARL5B | c.*1083del | 3'UTR (DEL) | VAF 37/116 reads (32%) | called by mutect2, pindel, varscan2
- ASL | c.*522C>T | 3'UTR (SNP) | VAF 11/78 reads (14%) | called by muse, mutect2
- ATG3 | c.863+102T>C | Intron (SNP) | VAF 10/54 reads (19%) | called by muse, mutect2, varscan2
- BMP6 | c.*613A>G | 3'UTR (SNP) | VAF 33/57 reads (58%) | called by muse, mutect2, varscan2
- BRD9 | c.966+453G>T | Intron (SNP) | VAF 15/43 reads (35%) | called by muse, mutect2, varscan2
- C8orf82 | c.157-291G>A | Intron (SNP) | VAF 30/60 reads (50%) | called by muse, mutect2, varscan2
- CALM1 | c.*3537G>A | 3'UTR (SNP) | VAF 7/28 reads (25%) | called by muse, mutect2, varscan2
- CASP10 | c.1416-8928A>G | Intron (SNP) | VAF 9/83 reads (11%) | called by muse, mutect2, varscan2
- CASP2 | c.*833C>A | 3'UTR (SNP) | VAF 13/177 reads (7%) | called by muse, mutect2
- CLIC2 | c.*1305_*1306del | 3'UTR (DEL) | VAF 8/25 reads (32%) | catalogued as rs1469151068; called by pindel, varscan2
- CNTN4 | c.*1109T>C | 3'UTR (SNP) | VAF 27/106 reads (25%) | called by muse, mutect2, varscan2
- COL4A1 | c.552+24G>A | Intron (SNP) | VAF 26/29 reads (90%) | called by muse, mutect2, varscan2
- COL4A3 | c.1029+56G>A | Intron (SNP) | VAF 29/52 reads (56%) | called by muse, mutect2, varscan2
- COL4A3 | c.1029+57C>T | Intron (SNP) | VAF 30/53 reads (57%) | called by muse, mutect2, varscan2
- CPEB4 | c.*5033C>T | 3'UTR (SNP) | VAF 6/52 reads (12%) | called by muse, mutect2, varscan2
- CSAD | c.126+49T>C | Intron (SNP) | VAF 5/87 reads (6%) | called by muse, mutect2
- DDTL | c.*832C>A | 3'UTR (SNP) | VAF 8/18 reads (44%) | called by muse, mutect2, varscan2
- DIP2B | c.*1231_*1234del | 3'UTR (DEL) | VAF 3/27 reads (11%) | called by mutect2, pindel
- DNAI4 | c.*638T>C | 3'UTR (SNP) | VAF 23/37 reads (62%) | called by muse, mutect2, varscan2
- DSC2 | c.-331A>G | 5'UTR (SNP) | VAF 17/54 reads (31%) | called by muse, mutect2, varscan2
- EBF1 | c.*1104C>A | 3'UTR (SNP) | VAF 14/83 reads (17%) | called by muse, mutect2, varscan2
- EFCAB14 | c.*1735A>G | 3'UTR (SNP) | VAF 43/143 reads (30%) | called by muse, mutect2, varscan2
- ELAVL2 | chr9:23691022 ins T | 3'Flank (INS) | VAF 14/70 reads (20%) | catalogued as rs920483656; called by mutect2, varscan2
- ELK4 | c.*5657A>C | 3'UTR (SNP) | VAF 18/98 reads (18%) | called by muse, mutect2, varscan2
- ENDOV | c.-26G>A | 5'UTR (SNP) | VAF 83/84 reads (99%) | catalogued as rs762529409, COSV60497242; called by muse, mutect2, varscan2
- GSTA2 | c.*56C>A | 3'UTR (SNP) | VAF 90/187 reads (48%) | catalogued as rs1803683; called by muse, mutect2, varscan2
- HEYL | c.*522C>T | 3'UTR (SNP) | VAF 6/57 reads (11%) | called by mutect2, varscan2
- IKZF4 | c.-63-328G>T | Intron (SNP) | VAF 6/44 reads (14%) | called by muse, mutect2, varscan2
- IL7R | c.*809C>T | 3'UTR (SNP) | VAF 12/51 reads (24%) | called by muse, mutect2, varscan2
- INTS8 | chr8:94822889 G>A | 5'Flank (SNP) | VAF 17/138 reads (12%) | called by muse, mutect2, varscan2
- IREB2 | c.1023+152C>T | Intron (SNP) | VAF 90/215 reads (42%) | catalogued as COSV51922899; called by muse, mutect2, varscan2
- MMP16 | c.*9237G>A | 3'UTR (SNP) | VAF 14/29 reads (48%) | called by muse, mutect2, varscan2
- NIPAL3 | c.*265_*278del | 3'UTR (DEL) | VAF 8/64 reads (13%) | called by mutect2, pindel, varscan2
- NR3C1 | c.*1C>A | 3'UTR (SNP) | VAF 14/53 reads (26%) | called by muse, mutect2, varscan2
- NR3C2 | c.*346G>A | 3'UTR (SNP) | VAF 14/83 reads (17%) | catalogued as rs1193242661; called by muse, mutect2, varscan2
- NREP | c.81+819_81+820del | Intron (DEL) | VAF 16/76 reads (21%) | called by pindel, varscan2
- OBSCN | c.18662-1540G>C | Intron (SNP) | VAF 5/98 reads (5%) | called by muse, mutect2
- PDE1C | c.*1480G>A | 3'UTR (SNP) | VAF 8/68 reads (12%) | catalogued as rs995575092; called by muse, mutect2, varscan2
- PEAK1 | c.*2499C>T | 3'UTR (SNP) | VAF 26/127 reads (20%) | called by muse, mutect2, varscan2
- PNO1 | c.*986A>G | 3'UTR (SNP) | VAF 19/32 reads (59%) | called by muse, mutect2, varscan2
- PSMD2 | c.2545-39T>G | Intron (SNP) | VAF 7/63 reads (11%) | called by muse, mutect2
- PTPRE | c.*2528C>T | 3'UTR (SNP) | VAF 13/80 reads (16%) | called by muse, mutect2, varscan2
- RAB3B | c.*2669T>C | 3'UTR (SNP) | VAF 23/65 reads (35%) | called by muse, mutect2, varscan2
- RICTOR | c.*3461A>C | 3'UTR (SNP) | VAF 7/108 reads (6%) | called by muse, mutect2
- SCIN | c.199+594T>C | Intron (SNP) | VAF 74/154 reads (48%) | catalogued as COSV51693267; called by muse, mutect2, varscan2
- SCYGR3 | chr2:227610373 C>T | 3'Flank (SNP) | VAF 22/89 reads (25%) | called by muse, mutect2, varscan2
- SERPINA10 | c.-51+110C>G | Intron (SNP) | VAF 9/47 reads (19%) | called by muse, mutect2, varscan2
- SOX11 | c.*6677C>T | 3'UTR (SNP) | VAF 44/75 reads (59%) | called by muse, mutect2, varscan2
- TGOLN2 | c.*387C>T | 3'UTR (SNP) | VAF 43/81 reads (53%) | called by muse, mutect2, varscan2
- TMEM81 | c.*246T>C | 3'UTR (SNP) | VAF 22/91 reads (24%) | called by muse, mutect2, varscan2
- TMSB4X | chrX:12975349 G>A | 5'Flank (SNP) | VAF 7/48 reads (15%) | catalogued as COSV104432400; called by muse, mutect2, varscan2
- TRAK1 | c.1744+1057C>T | Intron (SNP) | VAF 25/82 reads (30%) | called by muse, mutect2, varscan2
- TSC22D2 | c.-682C>T | 5'UTR (SNP) | VAF 6/45 reads (13%) | called by muse, mutect2, varscan2
- UTP15 | c.*623A>G | 3'UTR (SNP) | VAF 26/81 reads (32%) | called by muse, mutect2, varscan2
- ZNF212 | c.*927C>T | 3'UTR (SNP) | VAF 13/142 reads (9%) | called by muse, mutect2
